TCGA case TCGA-96-7545 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Washington University - NYU. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4ca13c92-84b4-4edf-842a-b20b7e713415

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 73 years; Vital status: Dead; Days to death: 1,736 days (4.8 years).

Diagnoses (4)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 73.2 years (26,729 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,736 days (4.8 years).
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 71.9 years (26,276 days); Days to diagnosis: -453 days (-1.2 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -453 days (-1.2 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Laterality: Bilateral; Classification of tumor: Prior primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 77.8 years (28,422 days); Days to diagnosis: 1,693 days (4.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 1,693 days (4.6 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 1,693 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,693 days (4.6 years); Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Follow-up contacts recording only the day: day 1,324, day 1,344, day 1,736.

Other clinical attributes
- DLCO (% of predicted): 57; FEV1/FVC after bronchodilator (%): 65; FEV1/FVC before bronchodilator (%): 61; FEV1 after bronchodilator (% of reference): 55; FEV1 before bronchodilator (% of reference): 52.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 116; Tobacco smoking quit year: 2005.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-96-7545-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.4; Intermediate dimension: 0.4; Shortest dimension: 0.1.
  Slide TCGA-96-7545-01A-01-BS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 32; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-96-7545-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-96-7545-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Lower; Pulmonary function test indicator: Yes.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Progressive Disease; New tumor event surgery: Yes; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; Treatment outcome at TCGA followup: Progressive Disease.
- Follow-up form 2, New neoplasm event types: New tumor event type: Locoregional Recurrence.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Lung; Other malignancy laterality: Both; Other malignancy histological type: Lung Adenocarcinoma- Not Otherwise Specified (NOS).
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Lung; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form 2, Surgery: Other malignancy surgery type: Wedge Resection.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy bilateral LUAD. Prior malignancy R LUAD. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,736 days; disease-specific survival: event status not recorded, 1,736 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,693 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-96-7545-01A-21D-2041-01): tumor purity 0.4, ploidy 1.78, whole-genome doublings 0.
